Somatic mutation profile of tumor specimen C3N-03013-01 (aliquot CPT0245130009) from CPTAC case C3N-03013, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 59.6 years (21,782 days).
Specimen C3N-03013-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61dbf0b7-e133-4299-95c0-18f9a01310cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03013-31 (Blood Derived Normal), aliquot CPT0245170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcec6def-c76b-49d9-8917-685210fe5c02

The open-access MAF lists 88 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 16, Nonsense Mutation 7, Intron 4, 5'Flank 3, Frame Shift Del 2, RNA 2, Splice Region 1, 5'UTR 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 119/1029 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- C1orf158 | c.228G>A p.G76= | Splice Region (SNP) | VAF 9/202 reads (4%) | catalogued as COSV55346713; called by muse, mutect2
- CDH19 | c.602C>A p.P201Q | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs752220537, COSV50986535; called by muse, mutect2
- CHRNB2 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 24/577 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs1464861089, COSV63808022; called by muse, mutect2
- DNAJB11 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201740359; called by muse, mutect2
- DYDC1 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 18/272 reads (7%) | catalogued as rs963394240; called by muse, mutect2
- EVPL | c.2398C>T p.R800* | Nonsense Mutation (SNP) | VAF 27/462 reads (6%) | catalogued as rs201637285, COSV101646200; called by muse, mutect2
- HELZ2 | c.7159G>A p.G2387R (on ENST00000467148 / NM_001037335.2; = p.G1818R on NM_033405.3) | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747772820, COSV64442691; called by muse, mutect2
- HIPK4 | c.1093T>A p.S365T | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV99397047; called by muse, mutect2
- MAN2B2 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.37); catalogued as rs764012747; called by muse, mutect2
- MNT | c.963G>C p.Q321H | Missense Mutation (SNP) | VAF 21/321 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1206249316; called by muse, mutect2
- NAV1 | c.4010A>G p.Q1337R | Missense Mutation (SNP) | VAF 44/646 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99818204; called by muse, mutect2
- PKD1 | c.4804C>T p.R1602C | Missense Mutation (SNP) | VAF 120/1696 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748423575, CD163932; called by muse, mutect2
- RASAL1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs144694121; called by muse, mutect2
- SEC24B | c.1382A>G p.Y461C | Missense Mutation (SNP) | VAF 44/824 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs370271043; called by muse, mutect2
- SLC2A4RG | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs748717932, COSV55508300; called by muse, mutect2
- SPHK1 | c.256G>A p.E86K (on ENST00000392496 / NM_001355139.2; = p.E100K on NM_021972.4) | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1228394330, COSV100039530; called by muse, mutect2
- TRIM27 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); catalogued as rs1274934215, COSV65874145; called by muse, mutect2, varscan2
- TRIM48 | c.552G>A p.W184* | Nonsense Mutation (SNP) | VAF 36/504 reads (7%) | catalogued as COSV70160741; called by muse, mutect2
- TRIM9 | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 27/620 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.217); catalogued as rs750032734; called by muse, mutect2
- XIRP2 | c.3175G>T p.G1059C (on ENST00000628543; = p.G1234C on NM_152381.6) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54734514; called by muse, mutect2, varscan2
- ALPG | c.784G>C p.G262R | Missense Mutation (SNP) | VAF 34/446 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2
- AOAH | c.390+2_390+3del p.X130_splice | Splice Site (DEL) | VAF 19/177 reads (11%) | called by mutect2, varscan2
- AP3M1 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.192); called by muse, mutect2
- ATIC | c.1523G>A p.W508* | Nonsense Mutation (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- BHLHE23 | c.483G>A p.M161I (on ENST00000370346; = p.M177I on NM_080606.4) | Missense Mutation (SNP) | VAF 38/712 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2
- C2CD6 | c.492T>A p.D164E | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.068); called by muse, mutect2
- C2orf50 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 25/463 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- CD244 | c.337T>A p.S113T | Missense Mutation (SNP) | VAF 20/375 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.014); called by muse, mutect2
- CD58 | c.236del p.N79Ifs*5 | Frame Shift Del (DEL) | VAF 23/225 reads (10%) | called by mutect2, pindel
- CFAP46 | c.7731C>A p.H2577Q | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- CHRNA3 | c.898G>C p.V300L | Missense Mutation (SNP) | VAF 28/486 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYFIP2 | c.1773A>C p.E591D (on ENST00000616178 / NM_001291722.2; = p.E566D on NM_014376.4) | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- EFNB3 | c.125del p.F42Sfs*17 | Frame Shift Del (DEL) | VAF 22/170 reads (13%) | called by mutect2, pindel
- EFR3B | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- FAT1 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 14/217 reads (6%) | called by muse, mutect2
- FSIP2 | c.12796G>A p.E4266K | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2
- HSPBAP1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 18/345 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- MAN2B2 | c.1068G>T p.Q356H | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.034); called by muse, mutect2
- MAP4K1 | c.2054C>A p.S685* | Nonsense Mutation (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- NAV3 | c.5705A>G p.D1902G (on ENST00000397909 / NM_001024383.2; = p.D1880G on NM_014903.6) | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- NBEAL1 | c.4786C>G p.L1596V | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by mutect2, varscan2
- NDUFA4 | c.194A>T p.Y65F | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPHS1 | c.335A>C p.Q112P | Missense Mutation (SNP) | VAF 60/970 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA10 | c.1456A>G p.N486D | Missense Mutation (SNP) | VAF 83/1326 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- PCNX3 | c.3298C>G p.Q1100E | Missense Mutation (SNP) | VAF 42/496 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- PRPF6 | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 54/736 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- RTL1 | c.2390T>C p.I797T | Missense Mutation (SNP) | VAF 19/331 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- SLC49A3 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.03); called by muse, mutect2
- SLC9B2 | c.347T>G p.F116C | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SORCS1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.145); called by muse, mutect2
- SYNE1 | c.16856T>A p.M5619K (on ENST00000367255 / NM_182961.4; = p.M5548K on NM_033071.3) | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.006); called by muse, mutect2
- TIMMDC1 | c.33T>G p.F11L | Missense Mutation (SNP) | VAF 25/312 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- TYMP | c.649T>C p.S217P | Missense Mutation (SNP) | VAF 26/381 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UHRF1BP1 | c.3833A>G p.N1278S | Missense Mutation (SNP) | VAF 48/716 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- UMOD | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 62/796 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- ZIC1 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ZNF302 | c.561A>T p.E187D (on ENST00000627982; = p.E108D on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ZNF469 | c.8061T>A p.C2687* (on ENST00000437464; = p.C2715* on NM_001367624.2) | Nonsense Mutation (SNP) | VAF 40/606 reads (7%) | called by muse, mutect2
- ZNF69 | c.423T>A p.F141L (on ENST00000429654 / NM_001364730.1; = p.F127L on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/458 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ADORA2A | c.252C>G p.V84= | Silent (SNP) | VAF 33/524 reads (6%) | called by muse, mutect2
- BHLHE23 | c.484C>A p.R162= (on ENST00000370346; = p.R178= on NM_080606.4) | Silent (SNP) | VAF 38/706 reads (5%) | catalogued as COSV64846363; called by muse, mutect2
- CAPG | c.852G>T p.V284= | Silent (SNP) | VAF 14/276 reads (5%) | catalogued as rs751256464; called by muse, mutect2
- CCDC85A | c.588C>T p.L196= | Silent (SNP) | VAF 17/204 reads (8%) | catalogued as rs1479017307; called by muse, mutect2
- CLEC18B | c.1188C>T p.A396= | Silent (SNP) | VAF 27/902 reads (3%) | called by muse, mutect2
- MYH15 | c.4479C>T p.L1493= | Silent (SNP) | VAF 36/270 reads (13%) | catalogued as rs1247250032; called by muse, mutect2, varscan2
- OR2T11 | c.465G>T p.L155= | Silent (SNP) | VAF 31/243 reads (13%) | catalogued as COSV100424895; called by muse, mutect2, varscan2
- PARP4 | c.976A>C p.R326= | Silent (SNP) | VAF 27/402 reads (7%) | called by muse, mutect2
- PRPF6 | c.705A>G p.T235= | Silent (SNP) | VAF 54/737 reads (7%) | called by muse, mutect2
- RYR1 | c.8244G>A p.P2748= | Silent (SNP) | VAF 63/1080 reads (6%) | catalogued as rs749048565, COSV100614756; called by muse, mutect2
- SLC12A3 | c.1056A>C p.T352= | Silent (SNP) | VAF 22/618 reads (4%) | catalogued as COSV52636475; called by muse, mutect2
- TTPA | c.762C>T p.D254= | Silent (SNP) | VAF 13/319 reads (4%) | called by muse, mutect2
- VCPKMT | c.75T>C p.G25= | Silent (SNP) | VAF 19/524 reads (4%) | called by muse, mutect2
- WASHC2A | c.1464A>C p.G488= | Silent (SNP) | VAF 27/616 reads (4%) | called by muse, mutect2
- XDH | c.2952G>A p.E984= | Silent (SNP) | VAF 29/626 reads (5%) | catalogued as COSV65151437; called by muse, mutect2
- ZIC1 | c.1116G>T p.T372= | Silent (SNP) | VAF 24/314 reads (8%) | catalogued as rs147993210, COSV51557907, COSV51558058; ClinVar: likely benign; called by muse, mutect2
- BICDL2 | chr16:3036333 G>A | 5'Flank (SNP) | VAF 10/170 reads (6%) | catalogued as rs1289960613; called by muse, mutect2
- BICDL2 | chr16:3036334 C>A | 5'Flank (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- CA13 | c.37+660G>A | Intron (SNP) | VAF 24/289 reads (8%) | called by muse, mutect2
- EPPIN-WFDC6 | c.*19T>A | 3'UTR (SNP) | VAF 20/348 reads (6%) | called by muse, mutect2
- NDRG4 | c.373-25G>A | Intron (SNP) | VAF 22/280 reads (8%) | catalogued as rs374873823; called by muse, mutect2
- PKD1L2 | n.307C>G | RNA (SNP) | VAF 19/395 reads (5%) | called by muse, mutect2
- RNF217-AS1 | n.2352G>A | RNA (SNP) | VAF 15/209 reads (7%) | catalogued as rs1390642552; called by muse, mutect2
- SLC25A36 | c.385+3704dup | Intron (INS) | VAF 44/312 reads (14%) | called by mutect2, pindel, varscan2
- SLC48A1 | chr12:47770883 C>A | 5'Flank (SNP) | VAF 18/468 reads (4%) | called by muse, mutect2
- SORBS1 | c.442-850T>C | Intron (SNP) | VAF 27/498 reads (5%) | called by muse, mutect2
- UBE2D3 | c.-11A>G | 5'UTR (SNP) | VAF 17/410 reads (4%) | called by muse, mutect2
